MMRF case MMRF_1251 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2281b435-31fb-425f-82ea-c0248b0b55f5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 43.1 years (15,744 days); ISS stage: II; Days to last known disease status: 1,625 days (4.4 years); Days to last follow up: 1,625 days (4.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 213 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 1,142 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 1,142 days (3.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 834 days (2.3 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,156 days (3.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7420 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.03 mg/dL; Immunoglobulin G 2.44 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.0417 g/L; Beta 2 Microglobulin 4.75 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.82 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 226 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 46 g/L; Total Protein 7.5 g/dL; Glucose 6.38 mmol/L; C-Reactive Protein 0.03 mg/dL.
- Day 66 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 2.44 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.87 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.62 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 152 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 2.63 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 4.68 mmol/L.
- Day 288 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 3.36 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.17 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 337 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 3.13 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.07 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.69 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 48 g/L; Total Protein 7.1 g/dL; Glucose 5.28 mmol/L.
- Day 435 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 4.5 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.7 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.21 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.39 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 5.25 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 694 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 6.23 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.77 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.08 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 144 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.
- Day 813 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Immunoglobulin G 5.94 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 869 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.42 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.56 mmol/L.
- Day 911 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 1,065 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 39.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 6.54 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.94 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.02 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 5.56 mmol/L.
- Day 1,156 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.87 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 6 mmol/L.
- Day 1,247 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 45.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 9.05 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 1,401 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 35.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 1,436 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 6.7 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.12 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.12 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 1,534: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 53.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 7.04 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.33 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.
- Day 1,625 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 61.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 6.52 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 1.45 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -7: Weight: 91 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1251_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1251_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 66 days.
